Surgical pathology report (de-identified scan), TCGA case TCGA-50-5072, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5072-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LYMPH NODE, LEVEL 10 LYMPH NODE, BIOPSY -

ONE (1) OF ONE (1) LYMPH NODE WITH METASTATIC ADENOCARCINOMA WITH EXTRACAPSULAR EXTENSION.

PART 2: LYMPH NODE, LEVEL 5 LYMPH NODE, BIOPSY -

ONE (1) OF ONE (1) LYMPH NODE WITH METASTATIC ADENOCARCINOMA WITH EXTRACAPSULAR EXTENSION.

PART 3: LYMPH NODE, LEVEL 11 LYMPH NODE, BIOPSY -

ONE (1) OF ONE (1) LYMPH NODE WITH METASTATIC ADENOCARCINOMA.

PART 4: BONE, "PORTION OF FOURTH RIB", RESECTION -

SPECIMEN UNDERGOING DECALCIFICATION. ADDENDUM REPORT TO FOLLOW.

PART 5: LYMPH NODE, "LEVEL 11 LYMPH NODE #2", BIOPSY -

ONE (1) OF FIVE (5) LYMPH NODES WITH METASTATIC ADENOCARCINOMA.

PART 6: LUNG, LEFT UPPER LOBE, LOBECTOMY -

- A. POORLY-DIFFERENTIATED ADENOCARCINOMA, SOLID AND ACINAR TYPE WITH CLEAR CELL CHANGE ASSOCIATED WITH VISCERAL PLEURAL AND ANGIOLYMPHATIC INVASION WITH LYMPHANGITIC SPREAD ADJACENT TO TUMOR. DIAMETER 4.5 CM. ALL MARGINS FREE. MILD HOST LYMPHOCYTIC RESPONSE. PATHOLOGIC STAGE: ypT2 N2 M0.
- B. SIX (6) OF EIGHT (8) N1 LYMPH NODES POSITIVE FOR METASTATIC ADENOCARCINOMA.
- C. RESPIRATORY BRONCHIOLITIS WITH EMPHYSEMATOUS CHANGE.

Source: NCI Genomic Data Commons file 92e582c5-5448-454e-b06a-3db94a880f29 (TCGA-50-5072.0E998D45-BA74-4A11-8A14-E394299C9BBA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).